Surgical pathology report (de-identified scan), TCGA case TCGA-HF-7131, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-7131-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details								Histology at
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date
	BUFFY	FF		GAST				
	TUMOUR	FF		GAST				

[page 2 of 3]
nd staging								
Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiat ion	Pathologic al T	Pathologic al N	Clinical M
■	RESECT	stomach	6.5	adenocarcinoma	II	T2b	N0	MX
■	RESECT	stomach	6.5	adenocarcinoma	II	T2b	N0	MX

[page 3 of 3]
Histology Comments

Slide URL

invasion of full thickness of muscularis
propria into adventitia
invasion of full thickness of muscularis
propria into adventitia

Source: NCI Genomic Data Commons file 486af227-171a-450d-8299-e75c442193b7 (TCGA-HF-7131.ED007CB2-C018-45DF-9961-D2E44FE4F7ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).